MMRF case MMRF_2444 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/dbfe5764-c8e7-425e-9c97-85ab6eedf6d2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 81 years; Vital status: Dead; Days to death: 76 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 81.2 years (29,644 days); ISS stage: III; Days to last known disease status: 76 days; Days to last follow up: 76 days.
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 75 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 76.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 0): M Protein 4.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.395 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 21.2 mg/dL; Immunoglobulin G 4.38 g/L; Immunoglobulin A 77.4 g/L; Immunoglobulin M 0.0659 g/L; Beta 2 Microglobulin 8.29 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 3.62 ×10⁹/L; Absolute Neutrophil 3.14 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 92 µmol/L; Blood Urea Nitrogen 8.31 mmol/L; Calcium 2.26 mmol/L; Albumin 25.1 g/L; Total Protein 10.8 g/dL; Glucose 6.8 mmol/L; C-Reactive Protein 0.09 mg/dL.
- Day 74 (ECOG 4): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 4.1 g/L; Immunoglobulin A 2.18 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 5.03 µg/mL; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 7.06 ×10⁹/L; Absolute Neutrophil 4.84 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 65 µmol/L; Blood Urea Nitrogen 2.9 mmol/L; Calcium 2.28 mmol/L; Albumin 34.9 g/L; Total Protein 5.34 g/dL; Glucose 3.5 mmol/L.

Other clinical attributes
- Day -2: Weight: 52 kg; Height: 160 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2444_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_2444_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
